Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A40Q, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A40Q-01A (Primary Tumor).

Spec. Taken

7/14/12

INTERPRETATION AND DIAGNOSIS:

1) LYMPH NODES, LATERAL NECK (DISSECTION): METASTATIC PAPILLARY CARCINOMA INVOLVING FOUR (4) OF TWENTY-TWO (22) LYMPH NODES. THE LARGEST INVOLVED NODE MEASURES 1.4 CM. EXTRANODAL EXTENSION IS NOT IDENTIFIED.

2) THYROID (THYROIDECTOMY):
SPECIMEN TYPE:
TOTAL THYROIDECTOMY

1C0-0-3
carcinoma, papillary, tall cell
834413

TUMOR SITE:
RIGHT LOBE

Site: thyroid. NOS
C73.9 7-18-12 RD

HISTOLOGIC TYPE:

PAPILLARY CARCINOMA, TALL CELL VARIANT Per TSS on 7/12/12, tall cell variant 750%.

TUMOR SIZE:
GREATEST DIMENSION 2.5 CM

FOCALITY:

MULTIFOCAL- THERE ARE 3 ADDITIONAL PAPILLARY MICROCARCINOMAS (EACH 0.1 CM).

LYMPH NODES:

METASTATIC CARCINOMA IN 19 OF 40 LYMPH NODES. (15 OF 18 CENTRAL LYMPH NODES, PART 2; AND 4 OF 22 LATERAL NECK LYMPH NODES, PART 1).

EXTENT OF INVASION (Edition AJCC):

PRIMARY TUMOR:

pT3: MINIMAL EXTRATHYROIDAL EXTENSION

REGIONAL LYMPH NODES:

pN1b: METASTASIS TO CERVICAL NODES

DISTANT METASTASIS:

pMx: CANNOT BE ASSESSED

MARGINS:

MARGINS ARE UNINVOLVED.

DISTANCE OF INVASIVE CARCINOMA FROM NEAREST MARGIN: <1 MM.

SPECIFY MARGIN: ANTERIOR AND POSTERIOR

VENOUS/LYMPHATIC INVASION:

PRESENT

ADDITIONAL PATHOLOGIC FINDINGS:

THYROIDITIS, LYMPHOCYTIC

Source: NCI Genomic Data Commons file 4777f756-a44a-4f55-bc81-ddd24101f853 (TCGA-ET-A40Q.D0250E29-21AE-4A68-B3F4-2DD739A5D088.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).